Somatic mutation profile of tumor specimen 0DJHH2 from CCDI case PBBRXL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (605 days).
Specimen 0DJHH2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e5e6c99-a093-4c6b-885f-a14c74489da5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJHDU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/373e0866-cf94-49d3-ab65-cd546ef2ceb3

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC88B | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 151/342 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs575511947; called by muse, varscan2
- GSG1L2 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 204/492 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.455); catalogued as rs929856732; called by muse, varscan2
